Somatic mutation profile of tumor specimen MP2PRT-PARRYH-TMP1-A (aliquot MP2PRT-PARRYH-TMP1-A-1-0-D-A80I-36) from MP2PRT case MP2PRT-PARRYH, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Blood; Age at diagnosis: 5.5 years (2,016 days).
Specimen MP2PRT-PARRYH-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e35f3509-da51-4bd0-8575-b3f0ea3db611.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARRYH-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARRYH-NB1-A-1-0-D-A80I-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/631ba17e-9ba1-4c49-bb2d-e2d92261bc77

The open-access MAF lists 12 somatic variants for this specimen: 8 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 8, Silent 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EZH2 | c.1861G>A p.V621M (on ENST00000460911 / NM_001203247.2; = p.V626M on NM_004456.5) | Missense Mutation (SNP) | VAF 127/161 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs587783625, CM1110537, COSV57451459; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DOCK6 | c.2093G>A p.R698H | Missense Mutation (SNP) | VAF 179/413 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs758660476; called by muse, mutect2, varscan2
- GALNT8 | c.661G>T p.D221Y | Missense Mutation (SNP) | VAF 85/210 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV104383694; called by muse, mutect2, varscan2
- KCNT1 | c.2921G>A p.R974Q (on ENST00000488444; = p.R993Q on NM_020822.3) | Missense Mutation (SNP) | VAF 140/350 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV53714237; called by muse, mutect2, varscan2
- ROBO1 | c.737T>C p.V246A | Missense Mutation (SNP) | VAF 125/295 reads (42%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.995); catalogued as rs1346538291; called by muse, mutect2, varscan2
- THBS2 | c.139G>A p.G47R | Missense Mutation (SNP) | VAF 252/665 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs534741032; called by muse, mutect2, varscan2
- ABCA1 | c.467G>A p.G156E | Missense Mutation (SNP) | VAF 169/366 reads (46%) | SIFT tolerated (0.99); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRAM1L1 | c.829G>T p.A277S | Missense Mutation (SNP) | VAF 165/479 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.31); called by muse, mutect2, varscan2
- CHL1 | c.2106C>T p.D702= (on ENST00000397491 / NM_001253387.1; = p.D718= on NM_006614.4) | Silent (SNP) | VAF 10/288 reads (3%) | catalogued as rs1305075943; called by muse, mutect2
- DCST2 | c.924C>A p.L308= | Silent (SNP) | VAF 176/473 reads (37%) | called by muse, mutect2, varscan2
- EPHA3 | c.1011C>T p.N337= | Silent (SNP) | VAF 118/289 reads (41%) | catalogued as rs201113556, COSV60713386, COSV60728079; called by muse, mutect2, varscan2
- FAAP20 | c.138G>A p.T46= | Silent (SNP) | VAF 307/734 reads (42%) | catalogued as COSV101052052; called by muse, mutect2, varscan2
